Gene-level copy-number profile of tumor specimen ALCH-B1RN-TTP1-A from ALCHEMIST case ALCH-B1RN, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 55.1 years (20,130 days).
Specimen ALCH-B1RN-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file bda6380f-cfc1-4081-83bf-a0b2bb9accd4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1RN-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/19a03938-a0b0-4339-870e-b127c29de9f3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 4,047; copy number 2: 54,312; copy number 3: 443; copy number 4: 57; copy number 5: 11; copy number 11: 24.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:129,555,214–129,606,676, 2 genes: PLXND1, RN7SL752P.
- chr7:27,092,993–27,096,000, 1 gene (within-gene range 0–2): HOXA1.
- chr7:27,096,124–27,096,248, 1 gene (within-gene range 0–2): AC004079.3.
- chr8:41,660,441–41,665,566, 3 genes (within-gene range 0–2): MIR486-1, MIR486-2, AC113133.1.
- chr16:28,258,686–28,323,849, 3 genes: AC138904.3, SBK1, AC138904.1.
- chr16:28,341,437–28,363,508, 2 genes: AC138904.2, NPIPB6.
- chr16:58,665,109–58,684,770, 1 gene: SLC38A7.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 35 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:180,989,762–181,836,880, 1 gene, copy number 5 (within-gene range 3–5): SOX2-OT.
- chr3:181,231,737–181,813,702, 10 genes, copy number 5: RNU6-4P, FAUP2, AC068308.1, RPL7AP25, AC125613.1, AC125613.2, AC117415.1, SOX2, AC117415.2, RN7SL703P.
- chr3:181,952,343–183,428,778, 24 genes, copy number 11: LINC01206, RN7SKP265, AC012081.1, AC084211.1, LINC01994, EIF4EP3, LINC01995, AC021055.1, RPL7L1P8, LINC02031, AC083801.1, AC083801.2, AC069431.1, ATP11B, AC069431.2, AC092953.2, DCUN1D1, AC092953.1, MCCC1, MCCC1-AS1, LAMP3, MCF2L2, B3GNT5, RNA5SP151.

Autosomal genes at a single copy (total copy number 1): 1,198. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
